Somatic mutation profile of tumor specimen 0DUVUY from CCDI case PBCLXD, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of pelvis; Age at diagnosis: 14.6 years (5,348 days).
Specimen 0DUVUY: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6c40acb5-a792-47c3-8ec3-9842e9c49b79.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DUVT7 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/67c94940-5d92-4e2b-80fa-671386b9cd64

The open-access MAF lists 50 somatic variants for this specimen: 30 protein-altering or splice-affecting, 12 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 12, Intron 4, Nonsense Mutation 3, 3'UTR 2, 5'UTR 1, In Frame Del 1, Splice Site 1, 5'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 105/200 reads (53%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by mutect2, varscan2
- HEATR1 | c.5119_5121del p.E1707del | In Frame Del (DEL) | VAF 44/132 reads (33%) | catalogued as rs781364360; called by pindel, varscan2
- KALRN | c.232G>A p.V78M | Missense Mutation (SNP) | VAF 48/315 reads (15%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.998); catalogued as rs777198177, COSV99563909; called by muse, mutect2, varscan2
- KBTBD13 | c.485C>T p.T162M | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as rs1269389678, COSV71351326; called by muse, mutect2, varscan2
- KHNYN | c.1378C>T p.R460W | Missense Mutation (SNP) | VAF 56/214 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752220870, COSV99249670; called by muse, mutect2, varscan2
- MEIS1 | c.1075G>C p.V359L | Missense Mutation (SNP) | VAF 67/419 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.071); catalogued as COSV55483819, COSV55485372; called by muse, mutect2, varscan2
- OR5L1 | c.604G>T p.V202L | Missense Mutation (SNP) | VAF 77/304 reads (25%) | SIFT tolerated (0.44); PolyPhen benign (0.031); catalogued as rs1257981868; called by muse, mutect2, varscan2
- SETD2 | c.1270C>T p.R424* | Nonsense Mutation (SNP) | VAF 66/263 reads (25%) | catalogued as rs1278528667, COSV57432605; called by muse, mutect2, varscan2
- STK36 | c.1127C>T p.S376F | Missense Mutation (SNP) | VAF 34/236 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.074); catalogued as rs1369541398, COSV99830952; called by muse, mutect2, varscan2
- TELO2 | c.933G>A p.T311= | Splice Region (SNP) | VAF 39/106 reads (37%) | catalogued as rs1167542668; called by muse, mutect2, varscan2
- WASHC3 | c.473C>A p.S158* | Nonsense Mutation (SNP) | VAF 19/173 reads (11%) | catalogued as COSV99527632; called by muse, mutect2, varscan2
- WDR54 | c.13G>A p.E5K | Missense Mutation (SNP) | VAF 83/422 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.039); catalogued as rs1465190573; called by muse, mutect2, varscan2
- ADAM32 | c.2319-1G>T p.X773_splice | Splice Site (SNP) | VAF 22/224 reads (10%) | called by muse, mutect2, varscan2
- C10orf71 | c.2395G>T p.A799S | Missense Mutation (SNP) | VAF 12/260 reads (5%) | SIFT tolerated (0.79); PolyPhen benign (0); called by muse, mutect2
- CALHM6 | c.745T>C p.Y249H | Missense Mutation (SNP) | VAF 70/178 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- EP400 | c.1161G>C p.L387F | Missense Mutation (SNP) | VAF 16/356 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ERAP1 | c.866T>G p.L289R | Missense Mutation (SNP) | VAF 71/303 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- FAHD2A | c.751C>A p.Q251K | Missense Mutation (SNP) | VAF 73/332 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.213); called by muse, mutect2, varscan2
- FCHSD1 | c.1321G>T p.A441S | Missense Mutation (SNP) | VAF 93/327 reads (28%) | SIFT tolerated (0.53); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- FEZF2 | c.999T>A p.H333Q | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2
- LTN1 | c.2498C>A p.S833* | Nonsense Mutation (SNP) | VAF 19/291 reads (7%) | called by muse, mutect2
- MELTF | c.1141G>T p.D381Y | Missense Mutation (SNP) | VAF 53/271 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- MOCOS | c.1758C>A p.N586K | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- NIBAN3 | c.1009A>T p.T337S | Missense Mutation (SNP) | VAF 77/243 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- PAPPA | c.2153T>C p.I718T | Missense Mutation (SNP) | VAF 99/306 reads (32%) | SIFT tolerated (0.95); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- RASSF9 | c.356C>A p.A119D | Missense Mutation (SNP) | VAF 52/263 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- SLC9A5 | c.2264C>A p.P755Q | Missense Mutation (SNP) | VAF 70/208 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- TACC2 | c.5360C>A p.A1787D | Missense Mutation (SNP) | VAF 57/251 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.021); called by muse, mutect2
- TBL2 | c.1064A>G p.H355R | Missense Mutation (SNP) | VAF 18/238 reads (8%) | SIFT tolerated (0.35); PolyPhen benign (0.001); called by muse, mutect2
- TNIP3 | c.42C>G p.H14Q (on ENST00000509841 / NM_001244764.2; = p.H7Q on NM_001128843.2) | Missense Mutation (SNP) | VAF 79/233 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2
- ASTN2 | c.825C>A p.T275= | Silent (SNP) | VAF 77/229 reads (34%) | catalogued as COSV100530384; called by muse, mutect2, varscan2
- CCR5 | c.240T>C p.L80= | Silent (SNP) | VAF 198/336 reads (59%) | called by muse, mutect2, varscan2
- HECW2 | c.1632C>G p.G544= | Silent (SNP) | VAF 61/338 reads (18%) | catalogued as COSV99646067; called by muse, mutect2, varscan2
- MED12 | c.381G>A p.T127= | Silent (SNP) | VAF 57/74 reads (77%) | catalogued as rs202125318, COSV61358732; ClinVar: benign / likely benign / uncertain significance; called by muse, mutect2, varscan2
- POTEE | c.2136C>T p.N712= | Silent (SNP) | VAF 55/532 reads (10%) | catalogued as rs1488580379, COSV100388105; called by muse, mutect2, varscan2
- RTTN | c.4539A>G p.R1513= | Silent (SNP) | VAF 45/150 reads (30%) | called by muse, mutect2, varscan2
- SEPTIN12 | c.582C>T p.A194= | Silent (SNP) | VAF 102/260 reads (39%) | catalogued as rs748781072; called by muse, mutect2, varscan2
- SHMT1 | c.567C>T p.N189= | Silent (SNP) | VAF 64/175 reads (37%) | catalogued as rs774601867; called by muse, mutect2, varscan2
- SP110 | c.735C>A p.P245= | Silent (SNP) | VAF 65/281 reads (23%) | called by muse, mutect2, varscan2
- TMEM18 | c.207C>T p.I69= | Silent (SNP) | VAF 53/239 reads (22%) | called by muse, mutect2, varscan2
- XKR5 | c.1330C>T p.L444= | Silent (SNP) | VAF 15/254 reads (6%) | called by muse, mutect2
- ZNF45 | c.1209G>T p.L403= | Silent (SNP) | VAF 53/198 reads (27%) | catalogued as rs993102484; called by mutect2, varscan2
- FCGR3B | c.-10G>C | 5'UTR (SNP) | VAF 112/284 reads (39%) | catalogued as rs534675635, COSV54211876, COSV99670628; called by muse, mutect2, varscan2
- GFI1B | c.*22C>T | 3'UTR (SNP) | VAF 61/139 reads (44%) | catalogued as rs1487977761, COSV59747560; called by muse, mutect2, varscan2
- KRTAP4-9 | c.*15C>A | 3'UTR (SNP) | VAF 9/21 reads (43%) | called by muse, mutect2, varscan2
- MUC19 | chr12:40527170 T>A | 5'Flank (SNP) | VAF 11/209 reads (5%) | called by muse, mutect2
- NUP88 | c.1836-22C>G | Intron (SNP) | VAF 70/219 reads (32%) | catalogued as rs1456561262; called by muse, mutect2, varscan2
- PAX6 | c.10+60G>A | Intron (SNP) | VAF 30/106 reads (28%) | catalogued as rs990513756; called by muse, varscan2
- SCAF4 | c.2488+60C>T | Intron (SNP) | VAF 16/30 reads (53%) | catalogued as rs781416660; called by muse, mutect2
- WNK2 | c.6739+25C>A | Intron (SNP) | VAF 40/96 reads (42%) | called by muse, mutect2, varscan2
